CCDI case PBBTNX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a9d48fb6-6807-4ca3-8ac7-efe676e8ecb7

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 15.1 years (5,531 days).

Biospecimens (3 samples)
- Sample 0DH5U5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5VQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
